Gene-level copy-number profile of tumor specimen TCGA-22-5485-01A from TCGA case TCGA-22-5485, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.8 years (21,488 days).
Specimen TCGA-22-5485-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9f6f8145-717d-43fb-9b4c-2248f5248ba1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5485-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/429d59e4-e3ff-4ef6-bc99-af56783083a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 12,885; copy number 2: 37,482; copy number 3: 6,893; copy number 4: 1,594; copy number 5: 957.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5485-01A-01D-1631-01): tumor purity 0.72, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:21,304,468–21,464,758, 2 genes: AC110296.1, MIR7978.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 957 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,580,910–150,050,788, 112 genes, copy number 5 (broad region; genes not listed).
- chr3:150,050,729–150,080,117, 2 genes, copy number 5: AC022494.1, LINC01998.
- chr3:150,408,335–198,222,513, 843 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,885. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
